Surgical pathology report (de-identified scan), TCGA case TCGA-LN-A4MQ, project TCGA-ESCA (Esophageal Carcinoma), tissue source site ILSBIO, specimen TCGA-LN-A4MQ-01A (Primary Tumor).

[page 1 of 6]
Clinical Case Report

(For Collection of Cancerous Tissue)

1CD-0-3

Carcinoma, Squamous cell, NOS. 8070/3

Site: Esophagus, lower C15.5

10/2/12

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight	☐ Single ☒ Married	VIETNAMESE	
☒ Male ☐ Female	56 kg	☐ Divorced ☐ Widow	Blood Pressure	Heart Rate
			121/8	

HISTORY OF PRESENT ILLNESS
Chief Complaints: Trouble swallowing; fever
Symptoms: Weight loss.
Clinical Findings:
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☒ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 6]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY		
Menopausal Status ☐ Pre-menopausal ☐ Peri-Menopausal ☐ Post-menopausal	Date of First Menses	# of Pregnancies
	Date of Last Menses	# of Live Births
	Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____	
		☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration (yrs)	When Quit (yr)
☒ YES ☐ NO				
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration (yrs)	When Quit (yr)
☐ YES ☒ NO				
Drug Use				
Current Status	TYPE	Frequency	Duration (yrs)	When Quit (yr)
☐ YES ☒ NO				

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA					
Test	Result	Date	Test	Result	Date
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____	
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____	
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____	
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____	
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____	
B/T Cell Markers: _____					

[page 3 of 6]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy x		
MRI		
Biopsy x	CARCINOMA	

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Location of Suspected Involved Lymph Nodes		Location of Suspected Distant Metastasis
Clinical Staging		Date of Diagnosis
T3 N1 M0 Stage: III		

Treatment Information

SURGICAL TREATMENT		
Procedure		Date of Procedure
Resection of lower part of esophagus		
Primary Tumor		
Organ	Detailed Location	Size
Esophagus	lower	2.5 x 1.5 x 1 cm
Extension of Tumor		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes		
Dissected Lymph Nodes		
Distant Metastasis		
Organ	Detailed Location	Size
Surgical Staging		
T3 N1 M0 Stage: III		

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 6]
Pathology Form

Specimen Information

Collected by:

Date:

Preserved by:

Date:

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
12 min		13 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
esophagus TUMOR	2 x 1.5 x 1 cm	lower.	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 3 N 1 M 0		Stage: III	
Notes: nodes (M ₁ , M ₂) in Nitrogen			

[page 5 of 6]
Microscopic Description

Histological Pattern											
Cell Distribution			+	-	Structural Pattern			+	-		
Diffuse			✓		Streaming						
Mosaic					Storiform						
Necrosis					Fibrosis						
Lymphocytic Infiltration			✓		Palisading						
Vascular Invasion					Cystic Degeneration						
Clusterized					Bleeding						
Alveolar Formation					Myxoid Change						
Indian File					Psammoma/Calcification						

Cellular Differentiation															
Squamous		+	-	Adenomatous		+	-	Sarcomatous		+	-	Lymphomatous		+	-
Squamoid Cell		✓		Glandular cell				Round Cell				Large Cell			
Spindle Cell				Cell Stratification				Fibroblast				Small Cell			
Keratin				Secretion				Osteoblast				RS Cell/RS Like			
Desmosome				Intracyt. Vacuole				Lipoblast				Inflam. Cell			
Pearl				Gland formation				Myoblast				Plasma Cell			

Cellular Differentiation: Well Moderate X Poor

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis		✓		
Hyperchromatism			✓	
Nucleolar Prominent			✓	
Multinucleated Giant Cell			✓	
Mitotic Activity			✓	

Nuclear Grade: 0 1 2 3

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

Histological Diagnosis: Squamous cell carcinoma of the esophagus.
(moderately differentiated) **Grade:** II

Comments:

Pathologist

Date

[page 6 of 6]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION		+	-	STRUCTURAL PATTERN		+	-
Diffuse			☒	Streaming			
Mosaic		☒		Storiform			
Necrosis		☒		Fibrosis			
Lymphocytic Infiltration		☒		Palisading			
Vascular Invasion			☒	Cystic Degeneration			
Clusterized		☒		Bleeding			
Alveolar Formation			☒	Myxoid Change			
Indian File			☒	Psammoma/Calcification			

2. Cellular features:

Squamous		+	-	Adenomatous		+	-	Sarcomatous		+	-	Lymphomatous		+	-
Squamoid Cell		☒		Glandular cell				Round Cell				Large Cell			
Spindle Cell		☒		Cell Stratification				Fibroblast				Small Cell			
Keratin		☒		Secretion				Osteoblast				RS Cell/RS Like			
Desmosome		☒		Intracyt. Vacuole				Lipoblast				Inflam. Cell			
Pearl			☒	Gland formation				Myoblast				Plasma Cell			

Otherwise Specified: D₁ 70%, D₂ 60%, D₃ 60%, D₄ 60%, Necrosis 10%

2. Cellular Differentiation:

Well	Moderately	Poor
		☒

3. Nuclear Atypia:

Nuclear Appearance		0	I	II	III
Aniso Nucleosis				☒	☒
Hyperchromatism				☒	☒
Nucleolar Prominent				☒	☒
Multinucleated Giant Cell					☒
Mitotic Activity					☒
Nuclear Grade					

Histological Diagnosis: Squamous Cell Carcinoma G3

Comments: M₁, M₂: Carcinoma metastasized to LN-

Date

*(INTEGRATED REPORT OF FINDINGS BY CONTRIBUTOR AND

PATHOLOGIST STAFF FOR RESEARCH USE ONLY).

Reviewed: WAI	Date Reviewed: 10/2/12	

Source: NCI Genomic Data Commons file 43bc6c2a-47d7-4f22-8f49-1d6d7fe178ab (TCGA-LN-A4MQ.C42864D6-13D0-4492-B502-8B642E05B3A9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).